Gene-level copy-number profile of tumor specimen ALCH-B2TX-TTP1-A from ALCHEMIST case ALCH-B2TX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.4 years (19,877 days).
Specimen ALCH-B2TX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file be832d46-0a53-4155-99a3-b44c809ffe68.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2TX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/0217054b-7752-49ca-bd7f-187dd9d7695d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 84; copy number 1: 436; copy number 2: 56,641; copy number 3: 1,168; copy number 4: 21; copy number 6: 1; copy number 7: 33; copy number 9: 6; copy number 11: 1; copy number 12: 5.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:916,865–921,016, 1 gene: LINC02593.
- chr1:944,203–959,309, 1 gene (within-gene range 0–1): NOC2L.
- chr1:50,326,131–50,327,007, 1 gene: AL596275.1.
- chr1:143,811,359–143,825,837, 1 gene: AC239798.1.
- chr2:131,821,987–131,832,031, 2 genes: AC103564.3, AC103564.1.
- chr3:46,668,995–46,693,704, 1 gene: ALS2CL.
- chr3:126,988,594–127,037,392, 1 gene: PLXNA1.
- chr4:8,846,076–8,871,839, 2 genes: HMX1, AC116612.1.
- chr5:1,225,381–1,246,189, 1 gene: SLC6A18.
- chr9:136,249,973–136,306,901, 1 gene (within-gene range 0–2): CCDC187.
- chr9:136,322,303–136,327,323, 1 gene: DKFZP434A062.
- chr15:25,185,631–25,250,940, 36 genes (within-gene range 0–2): SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:1,153,106–1,230,184, 7 genes (within-gene range 0–2): CACNA1H, AC120498.3, AC120498.1, AC120498.6, TPSG1, AC120498.10, TPSB2.
- chr16:1,493,344–1,510,457, 1 gene (within-gene range 0–3): TELO2.
- chr16:67,277,510–67,289,499, 1 gene (within-gene range 0–2): PLEKHG4.
- chr16:89,159,146–89,195,492, 3 genes: LINC00304, LINC02138, CDH15.
- chr20:63,540,810–63,556,695, 3 genes: SRMS, AL121829.2, FNDC11.
- chr22:18,951,934–18,959,512, 1 gene: AC007326.2.
- chr22:19,018,043–19,018,916, 1 gene (within-gene range 0–1): AC000095.1.
- chr22:19,031,564–19,034,564, 1 gene: CA15P1.
- chr22:19,045,256–19,048,375, 2 genes (within-gene range 0–1): Y_RNA, DGCR11.
- chr22:20,979,462–21,014,292, 7 genes (within-gene range 0–2): AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP.
- chr22:21,011,384–21,014,217, 1 gene (within-gene range 0–2): AC002472.3.
- chr22:50,245,183–50,261,716, 2 genes: HDAC10, MAPK12.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 46 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,498,767, 5 genes, copy number 12: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1.
- chr8:143,758,153–143,771,870, 1 gene, copy number 6: AC105219.3.
- chr11:69,414,307–69,926,813, 13 genes, copy number 7: AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2.
- chr11:78,015,715–78,444,049, 17 genes, copy number 7–9 (within-gene range 2–9): AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728.
- chr22:23,939,998–23,942,798, 1 gene, copy number 11: AP000350.1.
- chr22:23,957,414–23,991,421, 9 genes, copy number 7: GSTT2B, AC253536.2, DDTL, AC253536.6, DDT, AC253536.7, AC253536.1, AC253536.5, GSTT2.

Autosomal genes at a single copy (total copy number 1): 436. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
